Surgical pathology report (de-identified scan), TCGA case TCGA-EJ-5498, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-EJ-5498-01A (Primary Tumor).

PATIENT HISTORY:

The patient is a [REDACTED] with a history of PSA value of 5.0 and tonsillectomy. The patient also has a history of biopsy on [REDACTED] this biopsy reveals bilateral poorly differentiated prostatic adenocarcinoma.

PRE-OP DIAGNOSIS: Prostate cancer.

POST-OP DIAGNOSIS: Same.

PROCEDURE: Radical retropubic prostatectomy.

CGA-EJ-5498

FINAL DIAGNOSIS:**PART 1:**

LYMPH NODES, RIGHT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 11 LYMPH NODES (0/11).

PART 2:

LYMPH NODES, LEFT PELVIC, EXCISION -
NO EVIDENCE OF NEOPLASIA IN 15 LYMPH NODES (0/15).

PART 3:

PROSTATE, BILATERAL SEMINAL VESICLES AND VAS DEFERENTIA, RADICAL PROSTATECTOMY -

- A. PROSTATE ADENOCARCINOMA, GLEASON SCORE $4 + 3 = 7$.
- B. MICROSCOPIC GLEASON PATTERN 5 IS SEEN AND ACCOUNTS FOR LESS THAN 1% OF THE TUMOR.
- C. THE CARCINOMA INVOLVES BOTH THE RIGHT AND LEFT LOBES AND HAS A GREATEST NODULAR DIAMETER OF 1.6 CM IN ONE HISTOLOGIC SECTION (SLIDE 3DD).
- D. THE CARCINOMA INVOLVES APPROXIMATELY 10% OF THE EXAMINED PROSTATE VOLUME.
- E. THE CARCINOMA IS ORGAN CONFINED AND SHOWS NO EVIDENCE OF EXTRACAPSULAR EXTENSION.
- F. BILATERAL SEMINAL VESICLES ARE FREE OF CARCINOMA.
- G. ALL EXAMINED SURGICAL RESECTION MARGINS ARE FREE OF CARCINOMA.
- H. PERINEURAL INVASION IS IDENTIFIED.
- I. MULTIFOCAL HIGH-GRADE PROSTATIC INTRA-EPITHELIAL NEOPLASIA (PIN) IS SEEN.
- J. PATHOLOGIC TNM STAGE: pT2c N0 MX.
- K. BACKGROUND PROSTATE TISSUE WITH NODULAR HYPERPLASIA AND CHRONIC INFLAMMATION.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY PROSTATE TUMORS**

CLINICAL DATA:	PSA value: 5
INVASIVE CA IDENTIFIED?:	Yes
TUMOR HISTOLOGY:	Adenocarcinoma NOS
PRIMARY GLEASON GRADE:	4
SECONDARY GLEASON GRADE:	3
GLEASON SUM SCORE:	7
GLEASON 4/5 PERCENTAGE:	60%
WEIGHT OF PROSTATE:	42.02gm
TUMOR SIZE:	Maximum dimension: 1.6 cm
LOBE LATERALITY:	Right and Left Lobes
PERCENT OF SPECIMEN INVOLVED BY TUMOR:	5 - 25%
MULTIFOCAL DISEASE:	Yes
HIGH GRADE PIN:	Yes - multifocal
EXTRAPROSTATIC EXTENSION:	No
PERINEURAL INVASION:	Yes
ANGIOLYMPHATIC INVASION:	No
SEMINAL VESICLE INVASION:	No
SURGICAL MARGIN INVOLVEMENT:	All surgical margins free of tumor
LYMPH NODES EXAMINED:	26
LYMPH NODES POSITIVE:	0
EXTRANODAL EXTENSION:	No
T STAGE, PATHOLOGIC:	pT2c
N STAGE, PATHOLOGIC:	pN0
M STAGE, PATHOLOGIC:	pMX
HISTOLOGIC GRADE:	G3-4, Poorly differentiated/undifferentiated

Source: NCI Genomic Data Commons file d59b96ea-6bbb-4242-a40e-d4c7da04c64b (TCGA-EJ-5498.53D058FD-5FAA-43AB-8A5E-B6F95134970B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).